Surgical pathology report (de-identified scan), TCGA case TCGA-97-A4M2, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-A4M2-01A (Primary Tumor).

[page 1 of 11]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. F/S RIGHT MIDDLE LOBE NODULE
2. STATION 9 LYMPH NODE, RIGHT CHEST
3. STATION 10 LYMPH NODE, RIGHT CHEST
4. COMPLETION OF RIGHT MIDDLE LOBECTOMY
5. STATION 4 LYMPH NODE
6. STATION 7 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies
Reason For Addendum #2: Molecular Studies
Reason For Addendum #3: Molecular Studies
Reason For Addendum #4: Biomarker Report

DIAGNOSIS:

1. LUNG, RIGHT MIDDLE LOBE: WEDGE RESECTION
- ADENOCARCINOMA, PAPILLARY PREDOMINANT (1.1 CM), SEE NOTE.
- THE STAPLE LINE MARGIN IS FREE OF TUMOR.

Note: The tumor consists of papillary (70%) and micropapillary (30%) components. Results of molecular studies will be reported in addenda.

2. LYMPH NODE, RIGHT LEVEL 9: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
3. LYMPH NODE, RIGHT LEVEL 10: BIOPSY
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

4. LUNG, RIGHT MIDDLE LOBE: COMPLETION LOBECTOMY

ICD-0-3

adenocarcinoma, w/ mixed subtypes

8255/3

Site: lung, @ middle lobe C34.2

hw
10/4/12

[page 2 of 11]
- NO RESIDUAL TUMOR IS SEEN.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- ONE INTRAPARENCHYMAL LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

5. LYMPH NODE, LEVEL 4: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

6. LYMPH NODE, LEVEL 7: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

Specimens: 1: F/S RIGHT MIDDLE LOBE NODULE

2: STATION 9 LYMPH NODE, RIGHT CHEST

3: STATION 10 LYMPH NODE, RIGHT CHEST

4: COMPLETION OF RIGHT MIDDLE LOBECTOMY

5: STATION 4 LYMPH NODE

6: STATION 7 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

right middle

Procedure: Lobectomy

Specimen Laterality: Right

Tumor Site: Middle lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

1.1cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus);

[page 3 of 11]
or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastases (pM): Not applicable

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

M smoker (100 pack-years) with hx of prostate cancer () and COPD, now with a 1.5 cm RML mixed solid and ground-glass nodule and multiple additional bilateral lung nodules.

MACROSCOPIC DESCRIPTION:

The specimen is received fresh, in six parts, each labeled with the patient's name.

1. Part one is labeled 'right middle lobe nodule'. It consists of a wedge shaped portion of lung measuring 11 x 5 x 2 cm. There is a staple line identified on the specimen, measuring 10 cm in length. There is a cut identified on the specimen measuring 1.5 cm in length. On further sectioning there is a gray white ill defined area measuring 1.1 x 1 cm is identified. This area is 0.3 cm from the staple line and 0.4 cm from the pleural surface. The staple line is inked blue. Further sectioning of the lung reveals spongy tan maroon parenchyma. One portion from the ill defined area is submitted for frozen section analysis. Representative sections are submitted.

2. Part two is labeled 'station #9 lymph node'. It consists of a single lymph node measuring 2.4 x 1.5 x 1 cm. The cut surface is grey-black. Entirely submitted in one cassette.

3. Part three is labeled 'station #10 lymph node'. It consists of multiple irregular fragments of grey-black lymph nodes measuring 1.5 x 0.8 x 0.5 cm in aggregate. Entirely submitted in one cassette.

4. Part four is labeled 'completion of right middle lobectomy'. It consists of a lobe of lung measuring 10.5 x 5.5 x 2 cm and weighing 38 grams. Two staple lines, measuring 8 cm and 6 cm in length are noted. The bronchial and vascular margins are identified. The serosal surface is grey-purple and shows a subpleural grey-black nodule measuring 0.9 x 0.8 cm. Sectioning reveals an unremarkable

[page 4 of 11]
red beefy lung parenchyma. The subpleural nodule likely represents the lymph node. No discrete mass lesions are noted. Representative sections are submitted.

5. Part five is labeled 'station #4 lymph node'. It consists of three irregular segments of grey-black lymph nodes ranging from 0.2 to 0.5 cm in greatest dimension. Entirely submitted in one cassette.

6. Part six is labeled 'station #7 lymph node'. It consists of a single grey-black lymph node measuring 0.8 x 0.5 x 0.3 cm. Entirely submitted in one cassette.

SUMMARY OF SECTIONS:

- 1A frozen section control, ill defined area
- 1B area adjacent to ill defined area
- 1C area adjacent to ill defined area
- 1D area adjacent to ill defined area
- 1E unremarkable lung parenchyma
- 1F stapled line
- 2A in toto
- 3A in toto
- 4A bronchial and vascular margins
- 4B entire subpleural nodule
- 4C-4E lung, representative
- 5A in toto
- 6A in toto

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

- 1. Lung, right middle lobe: wedge resection (FS)
- Invasive adenocarcinoma.

Intra-Operative Consultation #1 performed by

Final Diagnosis performed by

[page 5 of 11]
ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent on

The test is to be performed on tissue from case

. The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 1A appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to

where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by

ADDENDUM #2:

MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

Referring Physician

Body Site: Right middle lobe of lung

Specimen Type: Slides

Clinical Data: Adenocarcinoma

RESULTS: Wild-type gene.

INTERPRETATION:

No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor

[page 6 of 11]
prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer, 2005; 92:11-139

Pao W, Wang TY, et al. PLoS Medicine, 2005; 2(1):57-61

Eberhard DA, Johnson BE, et al. J Clin Oncol, 2005; 23:5900-5909

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8):2538-2544

CRC

DiFiore C, Blanchard F, et al. Br J Cancer, 2007; 96:1166-1169

Lievre A, Bachet J-B, et al. Cancer Res, 2006; 66:3992-3995,

[page 7 of 11]
This test was developed and its performance characteristics determined by . The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #2 performed by

ADDENDUM #3:

EGFR Mutation Analysis

Referring Physician:

Body Site: Right middle lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

[page 8 of 11]
COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 70% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361>GA (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

1. Azzoli CG, et al. J Clin Oncol. 2009; 27:6251-6266.
2. Jackman DM et al. Clin Carcinoma Res. 2009; 15:5267-5273
3. Mok TS, et al. N Engl J Med. 2009; 361:947-957
4. Sharma SV, et al. Nat Rev Carcinoma, 2007; 7:169-181.

DISCLAIMER:

This test was developed and its performance characteristics determined by . The laboratory is

[page 9 of 11]
regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #3 performed by

ADDENDUM 4:

INTEGRATED ONCOLOGY

Fluorescence In-Situ Hybridization (FISH)

Referring Physician

Body Site: Right middle lobe of lung

Clinical Data: Adenocarcinoma

INTERPRETATION:

Negative for a rearrangement involving the ALK gene.

Probe #Nuclei Examined % Positive Nuclei %

Control values

2p23(ALK) 50 0.0 <15

[page 10 of 11]
A total of 50 cells were scored.

FINDINGS:

FISH was performed on paraffin embedded tissue sections using the Vysis ALK Break Apart Probe for the ALK gene at 2p23 (FDA approved). When a rearrangement involving ALK is present, either inversion or translocation, one of the two fusion signals separates as one red and one green signal. In this specimen, separated signals were present in 0% of the nuclei scored. This result is within the normal limits.

COMMENTS: Three to four copies of ALK were observed in 26.0% of cells. This gain of intact ALK fusion hybridization signals represents an aneuploid population with extra copies of chromosome 2/2p ALK region. Additional copies of ALK are not uncommon in NSCLCs, although the significance of extra copies of the ALK gene in lung carcinoma is unclear at this time (Salido M. et al. J Thorac Oncol. 2011;6:21-27).

References: (1). Soda M, et al. Identification of the transforming EML4-ALK fusion gene in non-small cell lung cancer. Nature. 2007;448:561-566; (2). Rodrig S, et al. Unique clinicopathologic features characterize ALK-rearranged lung adenocarcinoma in the western population. Clin Cancer Res. 2009;15:5216-5223; (3). Shaw A, et al. Clinical features and outcome of patients with non-small cell lung cancer who harbor EML4-ALK. J Clin Oncol. 2009;27:4247-4253; (4). Koivunen J, et al. EML4-ALK fusion gene and efficacy of an ALK kinase Inhibitor in lung cancer. Clin Cancer Res. 2008;14:4275-4283; (5). Kwak EL. et al. Anaplastic lymphoma kinase inhibition in non-small cell lung cancer. N Engl J Med. 2010;363(18):1693-1703; (6). The FDA approved Vysis ALK Break Apart FISH Probe Kit.

ISCN RESULTS: nuc ish(ALKx3 4)[59/100]

Electronically signed by:

Date:

The Vysis ALK Break Apart Probe FISH test () is FDA approved for use in the detection of rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens.

[page 11 of 11]
Addendum #4 performed by

The electronic signature attests that the Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

HIF-1A Discrepancy		✓
Prior Malignancy History	Prostate - No rx ✓	✓
Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 5f9f1019-4dca-45a9-b9bf-8f4ab18581ab (TCGA-97-A4M2.0D5976EC-5D41-44A2-AC0A-CBE90F2A908E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).